Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A42L, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A42L-06A (Metastatic).

Addendum

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Block D:

BRAF complex mutation IDENTIFIED (p.V600K, c.1798G>A, c.1799T>A).

NOTE:

The quantity and quality of the isolated DNA was acceptable for testing.

BACKGROUND:

Mutations in the **BRAF** gene are found in ~50-60% of melanomas with **BRAF** V600E as the most common mutation type (90%) followed by V600K, V600D, and V600R (1,2). Rarely, mutations are identified in other codons of the **BRAF** gene, including codon 601 (K601E mutation) (3). Targeted therapy using selective **BRAF** inhibitors (i.e. PLX4032) may be effective in cases with **BRAF** mutations (4-6). However, not all tumors reveal such correlation and, therefore, the results of mutational testing should be interpreted in the context of the histologic findings and the patient's clinical history.

1. Fecher LA et al. Toward a molecular classification of melanoma. *J Clin Oncol*. 2007 20;25(12):1606-20.
2. Willmore-Payne et al. Human malignant melanoma: detection of **BRAF**- and c-kit activating mutations by high-resolution amplicon melting analysis. *Hum Pathol* 2005 36:486-93.
3. Ellerhorst et al. Clinical correlates of **NRAS** and **BRAF** mutations in primary human melanoma. *Clin Cancer Res* 2010 October 25.
4. Smalley KS et al. Genetic subgrouping of melanoma reveals new opportunities for targeted therapy. *Cancer Res* 2009 69:3241-4.
5. Sondak et al. Targeting mutant **BRAF** and **KIT** in metastatic melanoma: ASCO 2009 meeting report. *Pigment Cell Melanoma Res* 2009, 22:386-387.
6. Yang H, et al. RG7204 (PLX4032), a Selective **BRAF**V600E Inhibitor, Displays Potent Antitumor Activity in Preclinical Melanoma Models. *Cancer Res*. 2010 Jun 15. [Epub ahead of print].

BRAF MUTATIONAL ANALYSIS:

For surgical specimens, manual microdissection was performed. Specimens with the minimum of 50% of tumor cells in a microdissection target are accepted for the analysis. DNA was isolated using standard laboratory procedure. Optical density readings were obtained. For the detection of mutation, DNA was amplified with primers flanking **BRAF** exon 15 sequence. The quality of amplified PCR product was evaluated by agarose gel electrophoresis. Then, bidirectional Sanger sequencing was performed using the BigDye Terminator Kit on ABI3130 (Applied Biosystems). The known hotspots were analyzed for the presence of mutations with Mutation Surveyor V3.01 (SoftGenetics). The limit of detection is approximately 20% of mutant alleles present in the background of normal DNA.

Addendum

Immunostaining for S100 and HMB45 is positive (confirming the diagnosis of melanoma).

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

ADRENAL GLAND, RIGHT, ADRENALECTOMY (29 GRAMS)-

- A. METASTATIC MELANOMA, 3 CM, EXTENDING TO MARGIN.
- B. VASCULAR INVASION (ADRENAL VEIN) IS IDENTIFIED.

PATIENT HISTORY:

CHIEF COMPLAINT/POST-OP/POST-OP DIAGNOSIS: Right adrenal mass.

PROCEDURE: Not answered.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

ICD-O3
melanoma, NOS
8720/3
Site: adrenal gland, NOS
8749
9-1-12
RD

Source: NCI Genomic Data Commons file 81d646cb-4a6c-4c34-a884-bc1a5bb22ef5 (TCGA-ER-A42L.5E762EB5-6918-4664-BE67-DDB70F19056D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).